Somatic mutation profile of tumor specimen TCGA-55-8511-01A (aliquot TCGA-55-8511-01A-11D-2393-08) from TCGA case TCGA-55-8511, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.9 years (26,986 days).
Specimen TCGA-55-8511-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 55899746-38e3-4a9c-87c2-dac4de6b693e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8511-10A (Blood Derived Normal), aliquot TCGA-55-8511-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7950351-3e23-423f-b59d-4a3a0d411fa9

The open-access MAF lists 603 somatic variants for this specimen: 449 protein-altering or splice-affecting, 138 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 384, Silent 138, Nonsense Mutation 32, Splice Site 12, Frame Shift Del 12, RNA 9, Frame Shift Ins 6, Intron 4, Splice Region 3, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1517G>T p.G506V (on ENST00000288602 / NM_001374244.1; = p.G466V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/188 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121913351, CM115083, COSV56057462, COSV56059390, COSV56070593; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.3342C>A p.F1114L | Missense Mutation (SNP) | VAF 32/107 reads (30%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV99285864; called by muse, mutect2, varscan2
- AC098582.1 | c.1641G>T p.W547C | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985623; called by muse, mutect2, varscan2
- ADAM2 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.576); catalogued as COSV99697364; called by muse, mutect2, varscan2
- ADAMTS1 | c.2317G>C p.A773P | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV99536164; called by muse, mutect2, varscan2
- ADGRA3 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.228); catalogued as COSV99293313; called by muse, mutect2, varscan2
- ADGRB3 | c.2608-1G>T p.X870_splice | Splice Site (SNP) | VAF 47/203 reads (23%) | catalogued as COSV99485225; called by muse, mutect2, varscan2
- ADGRV1 | c.17372C>A p.T5791K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV101316020; called by muse, mutect2
- AEBP1 | c.3029C>A p.P1010H | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV99788807; called by muse, mutect2, varscan2
- AGBL1 | c.1027C>A p.P343T | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.523); catalogued as rs1355405401, COSV101223173; called by muse, mutect2, varscan2
- AHNAK2 | c.8606A>T p.Q2869L | Missense Mutation (SNP) | VAF 114/308 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV100317613; called by muse, mutect2, varscan2
- AHNAK2 | c.5192T>A p.L1731H | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100317616; called by muse, mutect2
- ALG8 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100220106; called by muse, mutect2, varscan2
- ALG9 | c.565+1G>T p.X189_splice | Splice Site (SNP) | VAF 11/60 reads (18%) | catalogued as COSV101211902; called by muse, mutect2, varscan2
- ANK2 | c.2981C>A p.P994Q | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100001780; called by muse, mutect2, varscan2
- ANK3 | c.6131G>T p.S2044I | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.424); catalogued as COSV99780122; called by muse, mutect2, varscan2
- ANLN | c.2087A>C p.K696T | Missense Mutation (SNP) | VAF 38/217 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.164); catalogued as COSV99732366; called by muse, mutect2, varscan2
- APCS | c.475T>A p.Y159N | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV99661336; called by muse, mutect2
- APH1A | c.685T>G p.F229V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99354405; called by muse, mutect2, varscan2
- APOB | c.5715G>A p.M1905I | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs754036439, COSV99265769; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGAP29 | c.206-1G>T p.X69_splice | Splice Site (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99558233; called by muse, mutect2, varscan2
- ARID2 | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV100536265; called by muse, mutect2, varscan2
- ARID2 | c.3920C>G p.S1307* | Nonsense Mutation (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100536266; called by muse, mutect2, varscan2
- ARMC4 | c.1336G>C p.D446H | Missense Mutation (SNP) | VAF 39/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99518607; called by muse, mutect2, varscan2
- ARMC9 | c.1450A>G p.M484V | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777406461, COSV100589740; called by muse, mutect2, varscan2
- ARSH | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV101139870; called by muse, mutect2, varscan2
- ATP8B4 | c.2449G>T p.A817S | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99465654; called by muse, mutect2, varscan2
- B3GNT7 | c.496G>T p.G166W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV99805921; called by muse, mutect2, varscan2
- BIRC5 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100051349; called by muse, mutect2
- BRD1 | c.2923G>C p.G975R (on ENST00000216267 / NM_001349940.1; = p.G1106R on NM_001304808.3) | Missense Mutation (SNP) | VAF 50/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99349816; called by muse, mutect2, varscan2
- BRINP1 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 33/150 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.174); catalogued as COSV99774274, COSV99775546; called by muse, mutect2, varscan2
- BROX | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV100572208; called by muse, mutect2, varscan2
- BRWD1 | c.2989A>G p.M997V | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100313464; called by muse, mutect2, varscan2
- CACNA1F | c.4072A>T p.T1358S | Missense Mutation (SNP) | VAF 88/163 reads (54%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); catalogued as COSV100544894; called by muse, mutect2, varscan2
- CACNA2D1 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as COSV100666695, COSV62371506; called by muse, mutect2
- CACNA2D4 | c.2026C>T p.H676Y | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV54962114; called by muse, mutect2
- CADM3 | c.936C>A p.Y312* (on ENST00000368125 / NM_001127173.3; = p.Y346* on NM_021189.5) | Nonsense Mutation (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100930342; called by muse, varscan2
- CALHM4 | c.635C>A p.P212H (on ENST00000368596 / NM_001366078.1; = p.P26H on NM_153036.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100888872; called by muse, mutect2, varscan2
- CASZ1 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100681433, COSV59733404; called by muse, mutect2, varscan2
- CBWD2 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 36/324 reads (11%) | catalogued as COSV99380549; called by muse, mutect2, varscan2
- CCDC80 | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.251); catalogued as COSV99244824; called by muse, mutect2, varscan2
- CCDC87 | c.620G>A p.C207Y | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV59580448, COSV59580583; called by muse, mutect2, varscan2
- CD109 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.012); catalogued as COSV99753707; called by muse, mutect2, varscan2
- CD300C | c.312C>A p.D104E | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58170189; called by muse, mutect2, varscan2
- CDC42EP1 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.113); catalogued as COSV99312492; called by muse, mutect2, varscan2
- CDH11 | c.138G>C p.Q46H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.497); catalogued as COSV51766420; called by muse, mutect2, varscan2
- CDH18 | c.1423G>T p.G475C | Missense Mutation (SNP) | VAF 79/299 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.852); catalogued as COSV56974475, COSV99938028; called by muse, mutect2, varscan2
- CENPN | c.989G>C p.R330T | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as COSV100001349; called by muse, mutect2, varscan2
- CEP170 | c.1303G>T p.G435C | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV100316225; called by muse, mutect2, varscan2
- CFAP44 | c.1858G>C p.V620L | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV99869627; called by muse, mutect2
- CFAP57 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1397955249, COSV65263962; called by muse, mutect2, varscan2
- CFAP65 | c.2049G>T p.K683N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.539); catalogued as COSV100445213; called by muse, mutect2, varscan2
- CFH | c.583G>T p.D195Y | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs756966643, COSV100661455, COSV62777639, COSV62778528; called by muse, mutect2, varscan2
- CFHR3 | c.430+1G>T p.X144_splice | Splice Site (SNP) | VAF 29/141 reads (21%) | catalogued as COSV100807587; called by muse, mutect2, varscan2
- CLCN1 | c.2741C>A p.P914H | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV100578100; called by muse, mutect2, varscan2
- CLSTN2 | c.813G>C p.Q271H | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV101515730; called by muse, mutect2
- CMTR2 | c.2181G>T p.M727I | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.541); catalogued as COSV100579176; called by muse, mutect2, varscan2
- CNTLN | c.2650G>T p.G884* | Nonsense Mutation (SNP) | VAF 17/184 reads (9%) | catalogued as COSV99264214; called by muse, mutect2
- COL1A2 | c.636A>C p.Q212H | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV99799835; called by muse, mutect2
- COL1A2 | c.2972G>A p.G991D | Missense Mutation (SNP) | VAF 23/119 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as CM062551, COSV99799837; called by muse, mutect2, varscan2
- COL22A1 | c.3610-1G>T p.X1204_splice | Splice Site (SNP) | VAF 103/246 reads (42%) | catalogued as COSV100278657; called by muse, mutect2, varscan2
- COL6A6 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773211435, COSV100650301; called by muse, mutect2
- CPA5 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.127); catalogued as rs1554409385, COSV100812340, COSV62568577; called by muse, mutect2, varscan2
- CREB5 | c.1121C>T p.P374L (on ENST00000357727 / NM_182898.4; = p.P367L on NM_004904.3) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63221043; called by muse, mutect2
- CSH1 | c.456+1G>A p.X152_splice | Splice Site (SNP) | VAF 32/195 reads (16%) | catalogued as rs1567785902, COSV100298340; called by muse, mutect2, varscan2
- CSMD1 | c.4366C>A p.L1456M (on ENST00000520002; = p.L1455M on NM_033225.6) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100148285, COSV59323949; called by muse, mutect2, varscan2
- CSMD2 | c.2595C>A p.D865E | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as COSV99590362; called by muse, mutect2
- CSPG5 | c.1550G>A p.S517N (on ENST00000383738 / NM_001206943.2; = p.S490N on NM_006574.4) | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV99273831; called by muse, mutect2, varscan2
- CTSA | c.601G>T p.G201W | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99509884; called by muse, mutect2
- CTSA | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51943724; called by muse, mutect2
- CWH43 | c.697G>T p.D233Y | Missense Mutation (SNP) | VAF 21/122 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV99893464; called by muse, mutect2, varscan2
- CXXC1 | c.1345C>A p.R449S | Missense Mutation (SNP) | VAF 40/178 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.029); catalogued as COSV99496407; called by muse, mutect2, varscan2
- CYB5D2 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1026656665, COSV100028956; called by muse, mutect2, varscan2
- CYC1 | c.362G>C p.C121S | Missense Mutation (SNP) | VAF 135/310 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100010406; called by muse, mutect2, varscan2
- DCAF12 | c.497C>A p.A166D | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.21); catalogued as COSV100778376, COSV63513691; called by muse, mutect2, varscan2
- DDX43 | c.950C>A p.P317H | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100946350; called by muse, mutect2, varscan2
- DDX6 | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99870376; called by muse, mutect2, varscan2
- DECR2 | c.149+2T>G p.X50_splice | Splice Site (SNP) | VAF 8/126 reads (6%) | catalogued as COSV54792053, COSV99556792; called by muse, mutect2
- DEFB112 | c.133C>A p.Q45K | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as COSV100452142, COSV100452143; called by muse, mutect2, varscan2
- DEPDC1B | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as rs1419020496, COSV99409627; called by muse, mutect2
- DERL2 | c.391G>T p.V131L | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV99342335; called by muse, mutect2, varscan2
- DHCR24 | c.1150G>C p.V384L | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as COSV100987813; called by muse, mutect2
- DHX38 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as rs557516542; called by muse, mutect2
- DISP3 | c.1796C>A p.S599Y | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99608719; called by muse, mutect2, varscan2
- DISP3 | c.3468G>T p.E1156D | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as COSV99608721; called by muse, mutect2, varscan2
- DMD | c.6190C>A p.Q2064K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.06); catalogued as COSV100819814; called by muse, mutect2, varscan2
- DMD | c.5068del p.H1690Tfs*31 | Frame Shift Del (DEL) | VAF 15/122 reads (12%) | catalogued as COSV99053155; called by mutect2, pindel, varscan2
- DMD | c.1268A>G p.Q423R | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99922660; called by muse, mutect2, varscan2
- DMD | c.1267C>A p.Q423K | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as CM098368, COSV99922661; called by muse, mutect2, varscan2
- DNAH17 | c.10971G>T p.R3657S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101102397; called by muse, mutect2, varscan2
- DNAH9 | c.6373C>A p.Q2125K | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99305975; called by muse, mutect2, varscan2
- DNAJC21 | c.28G>C p.V10L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV100331427; called by mutect2, varscan2
- DNAJC8 | c.187C>T p.Q63* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99746292; called by muse, mutect2
- DOCK5 | c.5089G>A p.D1697N | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.244); catalogued as COSV99376945; called by muse, mutect2, varscan2
- DPP10 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 40/201 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.824); catalogued as COSV100065844, COSV59671071; called by muse, mutect2, varscan2
- DPP10 | c.842C>A p.P281Q | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.965); catalogued as rs1416501116; called by muse, mutect2, varscan2
- DPP10 | c.1495C>G p.P499A | Missense Mutation (SNP) | VAF 31/126 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100065849; called by muse, mutect2, varscan2
- DSG3 | c.84+1G>T p.X28_splice | Splice Site (SNP) | VAF 27/146 reads (18%) | catalogued as rs776757048, COSV99934200; called by muse, mutect2, varscan2
- DST | c.9046G>T p.E3016* | Nonsense Mutation (SNP) | VAF 17/117 reads (15%) | catalogued as COSV99756349; called by muse, mutect2, varscan2
- EDA2R | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.193); catalogued as COSV99490693; called by muse, mutect2, varscan2
- EDIL3 | c.1382G>T p.W461L | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.066); catalogued as COSV99676591; called by muse, mutect2, varscan2
- EGFL6 | c.88G>C p.G30R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV100789887, COSV63633252; called by muse, mutect2, varscan2
- EIF4A1 | c.866C>T p.T289I | Missense Mutation (SNP) | VAF 41/184 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV99548967; called by muse, mutect2, varscan2
- EIF4A3 | c.569A>G p.D190G | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99484093; called by muse, mutect2, varscan2
- EIF4G3 | c.2344G>C p.V782L | Missense Mutation (SNP) | VAF 86/437 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99944339; called by muse, mutect2, varscan2
- ENPP4 | c.1033A>G p.M345V | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1421284577, COSV100320325; called by muse, mutect2, varscan2
- EOMES | c.1279A>C p.T427P | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99841985; called by muse, mutect2, varscan2
- EPHA8 | c.427C>T p.L143F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.163); catalogued as rs1333715861, COSV51281216; called by muse, mutect2, varscan2
- EPRS1 | c.2267G>T p.R756I | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.315); catalogued as COSV100859393; called by muse, mutect2, varscan2
- ERBIN | c.2779T>A p.F927I | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV99396905; called by muse, mutect2
- ESM1 | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101195661; called by muse, mutect2, varscan2
- EXPH5 | c.4423G>T p.G1475C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1421314925, COSV99761679; called by muse, mutect2, varscan2
- EYA1 | c.1194C>A p.D398E | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100379472; called by muse, mutect2, varscan2
- FAM184A | c.749G>T p.G250V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as COSV100137834; called by muse, mutect2
- FAM184A | c.747A>C p.E249D | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV100137835; called by muse, mutect2
- FBXO42 | c.1487G>T p.R496I | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.075); catalogued as rs998051765, COSV100981776; called by muse, mutect2, varscan2
- FBXO47 | c.744T>A p.N248K | Missense Mutation (SNP) | VAF 10/225 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100960734; called by muse, mutect2
- FCRL5 | c.2434G>T p.E812* | Nonsense Mutation (SNP) | VAF 26/180 reads (14%) | catalogued as COSV100708969; called by muse, mutect2, varscan2
- FFAR4 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101012273; called by muse, mutect2, varscan2
- FLCN | c.218G>T p.S73I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV99550424; called by muse, mutect2, varscan2
- FLRT2 | c.1231T>C p.W411R | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100420438; called by muse, mutect2, varscan2
- FLRT2 | c.1232G>T p.W411L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV100420440; called by muse, mutect2, varscan2
- FN3K | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1020258323, COSV100333286; called by muse, mutect2, varscan2
- FOLH1 | c.1623G>T p.W541C | Missense Mutation (SNP) | VAF 52/240 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.255); catalogued as COSV99923247; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200732425, COSV100436703; called by muse, mutect2, varscan2
- FRMPD4 | c.2301G>C p.Q767H | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); catalogued as COSV101042960; called by muse, mutect2, varscan2
- FRYL | c.4798G>A p.V1600M | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV99976984; called by muse, mutect2, varscan2
- FRZB | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1415736303, COSV54553283; called by muse, mutect2, varscan2
- FSCN3 | c.1384A>T p.S462C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.908); catalogued as COSV99757176; called by muse, mutect2, varscan2
- FTO | c.703A>T p.N235Y | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101150001, COSV101150260; called by muse, mutect2, varscan2
- GABRQ | c.484G>C p.V162L | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.017); catalogued as COSV100941280, COSV100941437; called by muse, mutect2, varscan2
- GALNT2 | c.1579G>C p.G527R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as COSV100795756; called by muse, mutect2, varscan2
- GBP3 | c.1160A>G p.D387G | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV99352522; called by muse, mutect2, varscan2
- GCN1 | c.5727G>C p.K1909N | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs796161157, COSV100325315; called by muse, mutect2, varscan2
- GEM | c.444G>T p.Q148H | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV99891363; called by muse, mutect2, varscan2
- GJA8 | c.425G>T p.R142L | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99569415; called by muse, mutect2, varscan2
- GNAT3 | c.725G>T p.R242I | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101242390; called by muse, mutect2, varscan2
- GOT2 | c.279C>A p.D93E | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.202); catalogued as COSV99803733; called by muse, mutect2, varscan2
- GPR17 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 21/147 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.047); catalogued as COSV55754422, COSV99760606; called by muse, mutect2, varscan2
- GPR26 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.156); catalogued as COSV52934759, COSV99500921; called by muse, mutect2, varscan2
- GPRC5B | c.741G>T p.W247C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100315100; called by muse, mutect2, varscan2
- GRHL3 | c.827C>A p.S276Y (on ENST00000350501 / NM_198174.3; = p.S281Y on NM_021180.3) | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV99359401; called by muse, mutect2, varscan2
- GRK1 | c.530G>T p.W177L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100175351; called by muse, mutect2, varscan2
- GRM8 | c.2584G>C p.A862P | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV100283182; called by muse, mutect2, varscan2
- GRSF1 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54655003, COSV99635732; called by muse, mutect2, varscan2
- GSAP | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99990217; called by mutect2, varscan2
- GSDMA | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as rs892559208, COSV100053695; called by muse, mutect2, varscan2
- GTF3C1 | c.5493C>A p.D1831E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs762698678, COSV100649435, COSV62244574; called by muse, mutect2, varscan2
- GTF3C1 | c.5492A>C p.D1831A | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.556); catalogued as COSV100649436; called by muse, mutect2, varscan2
- GUCY2D | c.3068G>C p.S1023T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.734); catalogued as COSV99644002; called by muse, mutect2
- HCFC2 | c.425T>G p.F142C | Missense Mutation (SNP) | VAF 55/221 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99983082; called by muse, mutect2, varscan2
- HERC2 | c.8258C>T p.P2753L | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99874035; called by muse, mutect2, varscan2
- HHIPL2 | c.236C>A p.A79D | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV100596868; called by muse, mutect2, varscan2
- HK2 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs750616279, COSV99309081; called by muse, mutect2
- HOXA7 | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs765294385, COSV99636477, COSV99636778; called by muse, mutect2, varscan2
- HR | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 50/169 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100455836; called by muse, mutect2, varscan2
- HTATSF1 | c.1431A>T p.E477D | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as COSV99511672; called by muse, mutect2, varscan2
- HTR6 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs201559988, COSV57033662; called by muse, mutect2, varscan2
- HYAL4 | c.994G>T p.G332* | Nonsense Mutation (SNP) | VAF 14/76 reads (18%) | catalogued as rs952665342, COSV99772246; called by muse, mutect2, varscan2
- HYAL4 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99772248; called by muse, mutect2, varscan2
- ICAM1 | c.143G>C p.C48S | Missense Mutation (SNP) | VAF 37/122 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99320841; called by muse, mutect2, varscan2
- IFI16 | c.1119C>A p.N373K | Missense Mutation (SNP) | VAF 19/160 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV99857617; called by muse, mutect2, varscan2
- IGFBP7 | c.578G>A p.W193* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | catalogued as COSV99825430; called by muse, mutect2, varscan2
- ILRUN | c.749G>A p.W250* (on ENST00000374023 / NM_024294.4; = p.W184* on NM_022758.6) | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as COSV100927237; called by muse, mutect2, varscan2
- IRX3 | c.700G>T p.G234W | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV100315291, COSV61667908; called by muse, mutect2, varscan2
- IRX4 | c.304T>A p.F102I | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); catalogued as COSV99180808; called by muse, varscan2
- IRX6 | c.356C>A p.A119E | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as COSV99306478; called by muse, mutect2, varscan2
- ISL1 | c.414G>T p.R138S | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100045430; called by muse, mutect2, varscan2
- ITGA8 | c.2483A>T p.H828L | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.876); catalogued as COSV100959231; called by muse, mutect2, varscan2
- ITGAV | c.1979A>T p.K660M | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.582); catalogued as COSV99655011; called by muse, mutect2
- ITPR2 | c.382A>T p.S128C | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99659354; called by muse, mutect2, varscan2
- KALRN | c.2688G>T p.Q896H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99564536; called by muse, mutect2, varscan2
- KCNB1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 26/199 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV100870471; called by muse, mutect2, varscan2
- KCND2 | c.443T>A p.L148Q | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.103); catalogued as COSV100476012; called by muse, mutect2, varscan2
- KCNH7 | c.3213C>A p.Y1071* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as COSV100148108; called by muse, mutect2, varscan2
- KEL | c.1420C>G p.Q474E | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as CM055969, COSV100786812, COSV100787090; called by muse, mutect2, varscan2
- KIAA0319 | c.1615A>T p.I539L | Missense Mutation (SNP) | VAF 110/563 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV100985587; called by muse, mutect2, varscan2
- KIF21B | c.3982C>T p.R1328* (on ENST00000422435 / NM_001252100.2; = p.R1315* on NM_017596.4) | Nonsense Mutation (SNP) | VAF 55/273 reads (20%) | catalogued as COSV100143315, COSV59757692; called by muse, mutect2, varscan2
- KIF2B | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.083); catalogued as rs774999118, COSV52129324; called by muse, mutect2, varscan2
- KLRC3 | c.166G>T p.D56Y | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as COSV101122910; called by muse, mutect2, varscan2
- KRTAP13-2 | c.30C>A p.F10L | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV101299640, COSV101299675; called by muse, mutect2, varscan2
- KRTAP24-1 | c.223A>T p.S75C | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as COSV100447426; called by muse, mutect2, varscan2
- LIPK | c.435G>T p.M145I | Missense Mutation (SNP) | VAF 29/266 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.904); catalogued as COSV101344980; called by muse, mutect2, varscan2
- LMAN2L | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 41/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377695164; called by muse, mutect2, varscan2
- LRFN5 | c.133G>T p.V45F | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99983988; called by muse, mutect2, varscan2
- LRIG3 | c.1323A>C p.L441F | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.127); catalogued as COSV100292648; called by muse, mutect2, varscan2
- LRP1B | c.7801G>T p.G2601W | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101257458; called by muse, mutect2
- LRP1B | c.5981G>T p.G1994V | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV101257460; called by muse, mutect2, varscan2
- LRRC4C | c.1739C>A p.P580H | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.258); catalogued as rs757812600, COSV53420384, COSV53427977, COSV53435420; called by muse, mutect2, varscan2
- LRRFIP2 | c.1242G>T p.M414I | Missense Mutation (SNP) | VAF 21/170 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.013); catalogued as COSV100368409; called by muse, mutect2, varscan2
- LRRFIP2 | c.1241T>A p.M414K | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as COSV100368410; called by muse, mutect2, varscan2
- LRRIQ1 | c.336G>T p.K112N | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101277719, COSV101277737; called by muse, mutect2, varscan2
- LUZP2 | c.460-2A>T p.X154_splice | Splice Site (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100419934; called by muse, mutect2, varscan2
- LYST | c.4862G>T p.R1621M | Missense Mutation (SNP) | VAF 31/198 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1302052407, COSV101089460; called by muse, mutect2, varscan2
- MAGEB1 | c.578G>T p.W193L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV100974984; called by muse, mutect2
- MAGEB4 | c.290C>A p.A97D | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.944); catalogued as COSV100854702; called by muse, mutect2, varscan2
- MAGEC1 | c.2017C>A p.Q673K | Missense Mutation (SNP) | VAF 68/240 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); catalogued as COSV99035707, COSV99595741; called by muse, mutect2, varscan2
- MAP1S | c.3009G>T p.W1003C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV100141049; called by muse, mutect2, varscan2
- MAP2K4 | c.814-1G>A p.X272_splice | Splice Site (SNP) | VAF 16/109 reads (15%) | catalogued as COSV62256340, COSV62261009; called by muse, mutect2, varscan2
- MBD5 | c.3485G>T p.R1162I | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV101290098; called by muse, mutect2, varscan2
- MED23 | c.1611G>C p.M537I | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100644744, COSV100645016; called by muse, mutect2, varscan2
- MEP1B | c.346A>G p.I116V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs369778774; called by muse, mutect2, varscan2
- MFSD11 | c.1183C>T p.Q395* | Nonsense Mutation (SNP) | VAF 37/219 reads (17%) | catalogued as COSV60627397; called by muse, mutect2, varscan2
- MGA | c.7993G>T p.D2665Y (on ENST00000219905 / NM_001164273.1; = p.D2456Y on NM_001080541.2) | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV54953340; called by muse, mutect2, varscan2
- MINAR1 | c.1472G>T p.C491F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV100548938; called by muse, mutect2, varscan2
- MINPP1 | c.509G>T p.S170I | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV100916760; called by muse, mutect2, varscan2
- MMP16 | c.587G>T p.S196I | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV54152340, COSV99688387; called by muse, mutect2, varscan2
- MROH2B | c.2056T>C p.C686R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.373); catalogued as rs763563582, COSV101270683; called by muse, mutect2, varscan2
- MTMR10 | c.345G>C p.K115N | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100076124, COSV100076252; called by muse, mutect2, varscan2
- MTMR11 | c.1768C>T p.R590C (on ENST00000439741 / NM_001145862.2; = p.R518C on NM_181873.3) | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs781099087, COSV54966534; called by muse, mutect2
- MUSK | c.144G>T p.M48I | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.005); catalogued as COSV99504301; called by muse, mutect2, varscan2
- MUSK | c.838T>C p.Y280H | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs977371051, COSV99504305; called by muse, mutect2, varscan2
- MYBL2 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99406389; called by muse, mutect2, varscan2
- MYH13 | c.5061G>T p.E1687D | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV99354123; called by muse, mutect2
- MYH7 | c.1454T>A p.L485Q | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100806146; called by muse, mutect2, varscan2
- MYH8 | c.3925C>A p.Q1309K | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.056); catalogued as rs1159709746, COSV101238415; called by muse, mutect2, varscan2
- NAGPA | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | PolyPhen benign (0); catalogued as COSV100392917; called by muse, mutect2, varscan2
- NBAS | c.3019C>T p.Q1007* | Nonsense Mutation (SNP) | VAF 43/202 reads (21%) | catalogued as COSV55732572; called by muse, mutect2, varscan2
- NCAPG2 | c.2060G>T p.S687I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99317034; called by muse, mutect2
- NCKAP5 | c.4772C>A p.P1591Q | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); catalogued as COSV100492272; called by muse, mutect2, varscan2
- NCOR2 | c.2291A>T p.Q764L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100657364; called by muse, mutect2, varscan2
- NEGR1 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100163681; called by muse, mutect2
- NEGR1 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV60841517, COSV99071307; called by muse, mutect2
- NFKBIL1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.955); catalogued as COSV101092912; called by muse, mutect2
- NIBAN1 | c.2134C>T p.L712F | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV100836400; called by muse, mutect2, varscan2
- NLRP11 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.015); catalogued as rs367712953; called by muse, mutect2, varscan2
- NLRP2 | c.1823G>A p.C608Y | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1568502248, COSV54755919, COSV99672307; called by muse, mutect2, varscan2
- NLRP3 | c.1946C>A p.P649H | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.131); catalogued as COSV60223635; called by muse, mutect2, varscan2
- NLRP7 | c.1000C>G p.L334V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1165057228, COSV100052702; called by muse, varscan2
- NPTX2 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99674926; called by muse, mutect2, varscan2
- NR4A3 | c.1099C>G p.L367V | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100432424; called by muse, mutect2
- NRBP1 | c.842C>G p.S281* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV99275041, COSV99275223; called by muse, mutect2, varscan2
- NUP153 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.63); catalogued as rs368609111; called by muse, mutect2, varscan2
- NXPE4 | c.1306G>T p.G436C (on ENST00000375478 / NM_001077639.2; = p.G152C on NM_017678.3) | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64943674; called by muse, mutect2, varscan2
- ODF2L | c.1624G>A p.A542T (on ENST00000317336; = p.A526T on NM_020729.3) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.023); catalogued as rs370305366; called by muse, mutect2, varscan2
- OR10K1 | c.72G>T p.Q24H | Missense Mutation (SNP) | VAF 58/171 reads (34%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); catalogued as COSV99193267, COSV99193596; called by muse, mutect2, varscan2
- OR10Q1 | c.105C>A p.F35L | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.059); catalogued as COSV100372286; called by muse, mutect2, varscan2
- OR10V1 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100275925; called by muse, mutect2, varscan2
- OR1L8 | c.608A>G p.E203G | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV100508551; called by muse, mutect2, varscan2
- OR1S1 | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 108/398 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100515403; called by muse, mutect2, varscan2
- OR2L2 | c.76G>A p.V26I | Missense Mutation (SNP) | VAF 88/379 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs376676364, COSV63547837; called by muse, mutect2, varscan2
- OR2L8 | c.538G>T p.V180F | Missense Mutation (SNP) | VAF 35/178 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.208); catalogued as COSV100594219, COSV61726459; called by muse, mutect2, varscan2
- OR2T1 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV100822311, COSV63542705; called by muse, mutect2, varscan2
- OR4C13 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV73648663; called by muse, mutect2, varscan2
- OR4K1 | c.721A>C p.T241P | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99579023; called by muse, mutect2
- OR51G2 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778896766, COSV100432081, COSV100432139; called by muse, mutect2, varscan2
- OR52A1 | c.420C>G p.H140Q | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1564853242, COSV100200503; called by muse, mutect2, varscan2
- OR52M1 | c.442C>G p.L148V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.357); catalogued as COSV100798591, COSV64171983; called by muse, mutect2, varscan2
- OR5B17 | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV100641904; called by muse, mutect2, varscan2
- OR5T2 | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 60/286 reads (21%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.468); catalogued as COSV100506902; called by muse, mutect2, varscan2
- OR6B1 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 51/254 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as COSV101281653; called by muse, varscan2
- OR6B1 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as COSV101281633, COSV101281654; called by muse, varscan2
- OR6S1 | c.342C>G p.F114L | Missense Mutation (SNP) | VAF 158/247 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.609); catalogued as COSV100289385; called by muse, mutect2, varscan2
- OR6Y1 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 35/201 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100225382; called by muse, mutect2, varscan2
- OR8J1 | c.304G>T p.G102* | Nonsense Mutation (SNP) | VAF 30/168 reads (18%) | catalogued as rs1460533570, COSV57316957, COSV57320625; called by muse, mutect2, varscan2
- OR8K1 | c.237C>A p.Y79* | Nonsense Mutation (SNP) | VAF 58/305 reads (19%) | catalogued as COSV99687322; called by muse, mutect2, varscan2
- OR8K3 | c.861G>T p.L287F | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.114); catalogued as COSV100449791, COSV57133140; called by muse, mutect2, varscan2
- ORC1 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as rs753124340, COSV100856673; ClinVar: uncertain significance; called by muse, mutect2
- OSBPL1A | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100111852; called by muse, mutect2, varscan2
- PADI3 | c.1235T>A p.V412D | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100968495; called by muse, mutect2, varscan2
- PAGE1 | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 209/357 reads (59%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.831); catalogued as COSV101093961; called by muse, mutect2, varscan2
- PALLD | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.094); catalogued as COSV99824847; called by muse, mutect2, varscan2
- PAPPA2 | c.1379T>C p.F460S | Missense Mutation (SNP) | VAF 26/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100866800; called by muse, mutect2, varscan2
- PARD3 | c.3889C>G p.Q1297E | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated, low confidence (0.91); PolyPhen probably damaging (0.966); catalogued as COSV100632111; called by muse, mutect2, varscan2
- PCDH11X | c.473A>T p.Y158F | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.174); catalogued as COSV100011904; called by muse, mutect2, varscan2
- PCDH11X | c.2229C>G p.D743E | Missense Mutation (SNP) | VAF 48/250 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53464460; called by muse, mutect2, varscan2
- PCDH15 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100221520, COSV57303116; called by muse, mutect2
- PCDH9 | c.2588A>T p.N863I | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762335291, COSV100120959; called by muse, mutect2, varscan2
- PCDHA5 | c.1539C>A p.S513R | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100972297, COSV65351011; called by muse, varscan2
- PCDHB10 | c.683T>C p.V228A | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.5); catalogued as COSV99504362; called by muse, mutect2, varscan2
- PCDHB7 | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as rs1554280116, COSV99176981; called by muse, mutect2, varscan2
- PCDHGA5 | c.2198C>T p.A733V | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs777450935, COSV53945633; called by muse, mutect2, varscan2
- PGR | c.420G>T p.W140C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV99678416; called by muse, mutect2
- PHF2 | c.2769G>C p.E923D | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.034); catalogued as COSV100823175; called by muse, mutect2, varscan2
- PHF3 | c.4336G>A p.V1446M | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100012809; called by muse, mutect2
- PHLDB1 | c.4083G>T p.W1361C | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99874484; called by muse, mutect2, varscan2
- PI4KB | c.1518C>T p.I506= (on ENST00000368873 / NM_001369623.1; = p.I518= on NM_002651.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 43/477 reads (9%) | catalogued as COSV99649799; called by muse, mutect2
- PIK3CG | c.1086G>T p.R362S | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV63255939; called by muse, mutect2, varscan2
- PITPNM2 | c.1916G>T p.R639L | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV99759018; called by muse, mutect2, varscan2
- PKHD1 | c.10384A>G p.I3462V | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs139742511, COSV64392408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLCB4 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as COSV99595548; called by muse, mutect2
- PLEC | c.7156G>C p.A2386P (on ENST00000322810 / NM_201380.4; = p.A2276P on NM_000445.5) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.099); catalogued as COSV100514464, COSV59630445; called by muse, mutect2, varscan2
- PLEKHA6 | c.2486G>T p.R829L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs752419730, COSV99692124; called by muse, mutect2
- POC5 | c.1462G>C p.A488P (on ENST00000428202 / NM_001099271.2; = p.A463P on NM_152408.2) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100994371; called by muse, mutect2, varscan2
- POM121L12 | c.230T>A p.L77H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as COSV101374884, COSV101374920; called by mutect2, varscan2
- POTEF | c.3181G>T p.E1061* | Nonsense Mutation (SNP) | VAF 20/204 reads (10%) | catalogued as COSV62540840; called by muse, mutect2, varscan2
- POTEH | c.80G>T p.W27L | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs752255329, COSV100624961; called by muse, mutect2, varscan2
- PPME1 | c.304A>G p.R102G | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.105); catalogued as COSV100076460; called by muse, mutect2, varscan2
- PPP1R12A | c.2420C>T p.T807I | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs761550105, COSV99700415; called by muse, mutect2, varscan2
- PRAME | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 37/159 reads (23%) | catalogued as COSV101287091, COSV67162582; called by muse, mutect2, varscan2
- PROX2 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV101507810; called by muse, mutect2, varscan2
- PRRC2C | c.1879G>A p.E627K (on ENST00000367742; = p.E625K on NM_015172.4) | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100145301; called by muse, mutect2
- PSME4 | c.1639G>T p.V547F | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.71); catalogued as COSV101122508; called by muse, mutect2, varscan2
- PTGFR | c.761T>C p.I254T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100882297; called by muse, mutect2, varscan2
- PTHLH | c.16G>C p.V6L | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99570911; called by muse, mutect2
- PTPRC | c.3073-1G>A p.X1025_splice | Splice Site (SNP) | VAF 34/179 reads (19%) | catalogued as COSV100722690; called by muse, mutect2, varscan2
- PTPRD | c.817del p.A273Qfs*4 | Frame Shift Del (DEL) | VAF 23/217 reads (11%) | catalogued as COSV61926373, COSV61949828; called by mutect2, pindel, varscan2
- PTPRD | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV100644866, COSV61987867; called by muse, mutect2, varscan2
- QPCT | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100621599; called by muse, mutect2
- RAD51AP2 | c.891C>A p.Y297* | Nonsense Mutation (SNP) | VAF 21/169 reads (12%) | catalogued as COSV101208347; called by muse, mutect2, varscan2
- RAD54L2 | c.3628A>T p.M1210L | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV99621374; called by muse, mutect2, varscan2
- RASGRF1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs538996118, COSV69179247; called by muse, mutect2, varscan2
- RASSF7 | c.67G>T p.G23W | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752836536, COSV100272619; called by muse, mutect2, varscan2
- RB1CC1 | c.2159A>T p.D720V | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99212275; called by muse, mutect2, varscan2
- REG1B | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100521394, COSV59304565; called by muse, mutect2, varscan2
- RELN | c.9606T>C p.S3202= | Splice Region (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100633823; called by muse, mutect2, varscan2
- RFC5 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV99969902; called by muse, mutect2, varscan2
- RGS12 | c.4220A>T p.Q1407L (on ENST00000336727; = p.Q759L on NM_198227.2) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV100122940; called by muse, mutect2, varscan2
- RIC1 | c.3217G>C p.D1073H | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.121); catalogued as COSV99317303; called by muse, mutect2, varscan2
- RIOK3 | c.105G>T p.L35F | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV100259333; called by muse, mutect2, varscan2
- RNF149 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99766598; called by muse, mutect2, varscan2
- RREB1 | c.441T>G p.H147Q | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100619389; called by muse, mutect2, varscan2
- RREB1 | c.1851G>C p.E617D | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100619390; called by muse, mutect2, varscan2
- RTL4 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100465994; called by muse, mutect2, varscan2
- RUFY3 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as rs376050610; called by muse, mutect2, varscan2
- RYR2 | c.6823C>G p.Q2275E | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as COSV100770412; called by muse, mutect2, varscan2
- RYR2 | c.10390T>A p.S3464T | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100770413; called by muse, mutect2, varscan2
- S100A12 | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 41/199 reads (21%) | catalogued as COSV100907166, COSV64199220; called by muse, mutect2, varscan2
- SACS | c.2377G>T p.D793Y | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV101207462; called by muse, mutect2, varscan2
- SALL1 | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV99174104; called by muse, mutect2, varscan2
- SATB2 | c.1127G>T p.S376I | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV99611357; called by muse, mutect2, varscan2
- SCN3A | c.4261G>A p.D1421N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.901); catalogued as rs1457401377, COSV99327123; called by muse, mutect2
- SECISBP2L | c.1856C>A p.S619Y (on ENST00000559471 / NM_001193489.2; = p.S574Y on NM_014701.4) | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99960383; called by muse, mutect2, varscan2
- SEL1L2 | c.781G>T p.V261L | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99533262; called by muse, mutect2
- SEMA3B | c.1820G>T p.R607L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV100312807, COSV57113095; called by muse, mutect2, varscan2
- SEMA3F | c.104C>A p.S35* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99137452; called by muse, mutect2
- SEPTIN14 | c.1274A>T p.K425M | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101193333; called by muse, mutect2, varscan2
- SERPINB11 | c.1168G>T p.A390S | Missense Mutation (SNP) | VAF 40/174 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV101236233; called by muse, mutect2
- SERPINF2 | c.634A>G p.T212A | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100131947; called by muse, mutect2, varscan2
- SI | c.1335G>T p.E445D | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100015644; called by muse, mutect2, varscan2
- SIGLEC12 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV52462218, COSV99389375; called by muse, mutect2, varscan2
- SIN3A | c.1839A>C p.E613D | Missense Mutation (SNP) | VAF 49/215 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100845155; called by muse, mutect2, varscan2
- SKI | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66014458; called by muse, mutect2
- SLC15A3 | c.673A>T p.S225C | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99928750; called by muse, mutect2, varscan2
- SLC17A6 | c.26T>G p.L9W | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99581507; called by muse, mutect2, varscan2
- SLC17A6 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as rs1163726883, COSV54134263, COSV99581508; called by muse, mutect2, varscan2
- SLC17A7 | c.221G>T p.C74F | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV99676848; called by muse, mutect2, varscan2
- SLC1A7 | c.1403T>A p.L468Q | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100439609; called by muse, mutect2, varscan2
- SLC22A7 | c.946C>A p.Q316K (on ENST00000372585 / NM_153320.2; = p.Q314K on NM_006672.3) | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs1193352423, COSV99240371; called by muse, mutect2, varscan2
- SLC26A7 | c.1676A>G p.E559G | Missense Mutation (SNP) | VAF 28/368 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99403426; called by muse, mutect2
- SLC27A3 | c.2153C>A p.A718E (on ENST00000271857; = p.A590E on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99669952; called by muse, mutect2
- SLC44A2 | c.1431G>T p.W477C | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100213228; called by muse, mutect2, varscan2
- SLC6A19 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT tolerated (0.45); PolyPhen benign (0.12); catalogued as rs1479401124, COSV100443482; called by muse, mutect2, varscan2
- SLC9A3 | c.793G>A p.G265R | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53805127; called by muse, mutect2
- SLCO5A1 | c.1775G>C p.S592T | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as COSV99480096; called by muse, mutect2, varscan2
- SLITRK3 | c.39G>C p.R13S | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as COSV99579297; called by muse, mutect2
- SLITRK4 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 65/231 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV100567363; called by muse, mutect2, varscan2
- SLITRK5 | c.1149G>T p.Q383H | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.109); catalogued as COSV100280786; called by muse, mutect2, varscan2
- SMAD4 | c.1555A>T p.K519* | Nonsense Mutation (SNP) | VAF 30/114 reads (26%) | catalogued as COSV100747834, COSV61693782; called by muse, mutect2, varscan2
- SNRPN | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100578132; called by muse, mutect2, varscan2
- SPATA18 | c.92A>G p.N31S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs767294350, COSV99730606; called by muse, mutect2, varscan2
- SPATA2L | c.1090G>A p.G364S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV99232326; called by muse, mutect2, varscan2
- SPATA7 | c.1621A>G p.I541V | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.678); catalogued as rs780618807, COSV99248027; called by muse, mutect2
- SPECC1 | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV99822063; called by muse, mutect2
- SPEF2 | c.3292G>A p.D1098N | Missense Mutation (SNP) | VAF 29/248 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100607489; called by muse, mutect2, varscan2
- SPTA1 | c.3918T>A p.S1306R | Missense Mutation (SNP) | VAF 90/261 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as rs777168896, COSV100935009; called by muse, mutect2, varscan2
- STAB1 | c.4378G>A p.A1460T | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.034); catalogued as rs373154327; called by muse, mutect2, varscan2
- STAMBP | c.508C>T p.R170W | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs774517823, COSV100277702; called by muse, mutect2, varscan2
- SULT1C3 | c.261C>A p.H87Q | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as COSV100227477; called by muse, mutect2
- SULT1C3 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100227479, COSV61252380; called by muse, mutect2, varscan2
- SYNE1 | c.20791C>T p.Q6931* (on ENST00000367255 / NM_182961.4; = p.Q6860* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 43/142 reads (30%) | catalogued as COSV99565290; called by muse, mutect2, varscan2
- SYNE2 | c.3748C>T p.H1250Y | Missense Mutation (SNP) | VAF 11/230 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV59946062; called by muse, mutect2
- SYT15 | c.817C>A p.L273M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV100970427; called by muse, mutect2, varscan2
- TACSTD2 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100973746; called by muse, mutect2
- TBR1 | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV101271475; called by muse, mutect2, varscan2
- TBX22 | c.851C>A p.T284N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.303); catalogued as COSV100960781; called by muse, mutect2, varscan2
- TECPR2 | c.3313A>T p.I1105L | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.056); catalogued as COSV100850013; called by muse, mutect2, varscan2
- TF | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV99395805; called by muse, mutect2, varscan2
- TFAP2B | c.77A>C p.Y26S | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.108); catalogued as COSV99540242; called by muse, mutect2, varscan2
- TFAP2B | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV99540245; called by muse, mutect2, varscan2
- TFAP2D | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as COSV99145938; called by muse, mutect2, varscan2
- TG | c.1805T>A p.V602E | Missense Mutation (SNP) | VAF 88/192 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV99601017; called by muse, mutect2, varscan2
- TGM7 | c.690C>T p.I230= | Splice Region (SNP) | VAF 22/88 reads (25%) | catalogued as COSV101476861; called by muse, mutect2, varscan2
- TLL1 | c.1115A>G p.Y372C | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.968); catalogued as COSV99287448; called by muse, mutect2, varscan2
- TMEM132B | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100169810; called by muse, mutect2, varscan2
- TNMD | c.424-1G>C p.X142_splice | Splice Site (SNP) | VAF 19/98 reads (19%) | catalogued as COSV65976952; called by muse, mutect2, varscan2
- TNN | c.139A>G p.K47E | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as rs1188311471, COSV99512039; called by muse, varscan2
- TNN | c.2450G>T p.W817L | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99512040; called by muse, varscan2
- TNR | c.768C>A p.Y256* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as COSV99689756; called by muse, mutect2, varscan2
- TP53 | c.886del p.H296Tfs*49 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as COSV52949796, COSV52994463, COSV53210146; called by mutect2, pindel, varscan2
- TRERF1 | c.20A>G p.Y7C | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100550790; called by muse, mutect2, varscan2
- TRPM1 | c.790G>T p.V264F | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56632164, COSV99855988; called by muse, mutect2, varscan2
- TRPM6 | c.3965C>A p.T1322K | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.058); catalogued as COSV100666381; called by muse, mutect2, varscan2
- TRRAP | c.7024A>G p.M2342V (on ENST00000359863 / NM_001244580.1; = p.M2324V on NM_003496.3) | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV100722418; called by muse, mutect2, varscan2
- TSBP1 | c.1095G>T p.K365N (on ENST00000617061; = p.K370N on NM_006781.5) | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV100898815; called by muse, mutect2, varscan2
- TSNAXIP1 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99535114; called by muse, mutect2, varscan2
- TTC7A | c.1687A>C p.K563Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.375); catalogued as COSV99766476; called by muse, mutect2, varscan2
- TTN | c.79918G>A p.G26640R (on ENST00000591111; = p.G19216R on NM_003319.4) | Missense Mutation (SNP) | VAF 20/147 reads (14%) | PolyPhen probably damaging (1); catalogued as COSV100614387; called by muse, mutect2, varscan2
- TTN | c.53827G>C p.D17943H (on ENST00000591111; = p.D10519H on NM_003319.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | PolyPhen benign (0.414); catalogued as rs765734391, COSV100614390; called by muse, mutect2, varscan2
- TTN | c.53759G>A p.G17920E (on ENST00000591111; = p.G10496E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | PolyPhen probably damaging (1); catalogued as rs372491628; called by muse, mutect2, varscan2
- TTR | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 16/91 reads (18%) | catalogued as COSV99379538; called by muse, mutect2, varscan2
- TXK | c.292C>G p.P98A | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.034); catalogued as COSV99972465; called by muse, mutect2, varscan2
- UBAP2L | c.1729C>T p.Q577* | Nonsense Mutation (SNP) | VAF 17/122 reads (14%) | catalogued as COSV99671362; called by muse, varscan2
- UBAP2L | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV99671365; called by muse, varscan2
- UBR5 | c.7560G>C p.K2520N | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV99640943; called by muse, varscan2
- UBR5 | c.7480G>A p.D2494N | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.167); catalogued as COSV99640945; called by muse, varscan2
- USH2A | c.7295C>T p.P2432L | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100235277; called by muse, mutect2, varscan2
- USH2A | c.3292A>T p.T1098S | Missense Mutation (SNP) | VAF 27/163 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV100235278; called by muse, mutect2, varscan2
- USP11 | c.2329G>A p.A777T (on ENST00000218348; = p.A734T on NM_001371072.1) | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.83); PolyPhen benign (0.045); catalogued as COSV99510946; called by muse, mutect2, varscan2
- VAV1 | c.2446G>T p.G816* | Nonsense Mutation (SNP) | VAF 40/97 reads (41%) | catalogued as COSV100409074, COSV58379493, COSV58386932; called by muse, mutect2, varscan2
- VCAN | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 35/157 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54113100; called by muse, mutect2, varscan2
- VHLL | c.99G>T p.E33D | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV100372635; called by muse, mutect2, varscan2
- VPS13B | c.3924G>T p.L1308F | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100662094; called by muse, mutect2, varscan2
- VPS13B | c.4795T>A p.S1599T | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100662111; called by muse, mutect2, varscan2
- WDFY1 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 39/370 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV99239472; called by muse, mutect2, varscan2
- WDPCP | c.1505A>G p.Y502C | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs559295906, COSV99705416; called by muse, mutect2, varscan2
- XIRP2 | c.8508A>T p.E2836D (on ENST00000628543; = p.E3011D on NM_152381.6) | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.877); catalogued as COSV99743200; called by muse, mutect2, varscan2
- XYLT1 | c.1601C>A p.T534K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV54479836, COSV99761910; called by muse, mutect2, varscan2
- ZACN | c.981C>A p.S327R | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV100135297; called by muse, mutect2
- ZFHX4 | c.7069G>A p.D2357N | Missense Mutation (SNP) | VAF 196/526 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV51463846, COSV51502150; called by muse, varscan2
- ZFHX4 | c.7843G>A p.E2615K | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV99263100; called by muse, mutect2, varscan2
- ZFP42 | c.800G>T p.R267L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.845); catalogued as COSV100478892, COSV58818370; called by muse, mutect2
- ZMAT3 | c.423C>G p.I141M | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs750676731, COSV100265215; called by muse, mutect2, varscan2
- ZNF284 | c.1424G>A p.R475K | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.178); catalogued as COSV101399001; called by muse, mutect2, varscan2
- ZNF334 | c.186G>T p.L62F | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100749087; called by muse, mutect2
- ZNF385C | c.1138C>A p.Q380K | Missense Mutation (SNP) | VAF 41/105 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV100288820; called by muse, mutect2, varscan2
- ZNF423 | c.1888G>T p.A630S (on ENST00000563137 / NM_001379286.1; = p.A622S on NM_015069.4) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.035); catalogued as COSV52186124, COSV99281800; called by muse, mutect2, varscan2
- ZNF560 | c.1750C>A p.R584S | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100038658; called by muse, mutect2, varscan2
- ZNF614 | c.1511T>A p.I504N | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99571803; called by muse, mutect2
- ZNF665 | c.833A>G p.E278G (on ENST00000600412; = p.E343G on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1372200171, COSV101128401; called by muse, mutect2, varscan2
- ZNF695 | c.653G>A p.G218D | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100377493; called by muse, mutect2, varscan2
- ZNF768 | c.643C>A p.P215T | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99411532; called by muse, mutect2, varscan2
- ZNF778 | c.368G>C p.G123A | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.539); catalogued as COSV100124334, COSV100124442; called by muse, mutect2, varscan2
- ZNF79 | c.979C>G p.H327D | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61071778; called by muse, mutect2, varscan2
- ZNF804A | c.670G>T p.V224L | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100168071; called by muse, mutect2, varscan2
- ZP4 | c.20T>C p.V7A | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100850688; called by muse, mutect2, varscan2
- ZSCAN20 | c.2293C>A p.P765T | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100792621; called by muse, mutect2, varscan2
- ZW10 | c.1603C>G p.P535A | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99562692; called by muse, mutect2, varscan2
- CFH | c.205_206delinsT p.G69* | Frame Shift Del (DEL) | VAF 25/211 reads (12%) | called by pindel, varscan2*
- CNOT1 | c.2076dup p.P693Afs*7 | Frame Shift Ins (INS) | VAF 19/166 reads (11%) | called by mutect2, pindel, varscan2
- CXorf21 | c.253del p.Q85Rfs*50 | Frame Shift Del (DEL) | VAF 41/298 reads (14%) | called by mutect2, pindel, varscan2
- DCDC1 | c.4919dup p.M1640Ifs*23 (on ENST00000597505 / NM_001367979.1; = p.M747Ifs*23 on NM_020869.3) | Frame Shift Ins (INS) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- ELMOD1 | c.539del p.G180Dfs*36 | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- ELOVL7 | c.273G>T p.W91C | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FLACC1 | c.53del p.G18Dfs*5 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel, varscan2
- FRG2 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GGTLC2 | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by mutect2, varscan2
- ITSN1 | c.4768del p.Q1590Kfs*9 | Frame Shift Del (DEL) | VAF 20/121 reads (17%) | called by mutect2, pindel, varscan2
- JADE2 | c.776dup p.R260Afs*9 | Frame Shift Ins (INS) | VAF 19/102 reads (19%) | called by mutect2, pindel, varscan2
- KCNH7 | c.3088del p.E1030Kfs*6 | Frame Shift Del (DEL) | VAF 28/245 reads (11%) | called by mutect2, pindel, varscan2
- LCE3E | c.221del p.G74Afs*45 | Frame Shift Del (DEL) | VAF 25/221 reads (11%) | called by mutect2, pindel, varscan2
- MAML2 | c.3037dup p.A1013Gfs*6 | Frame Shift Ins (INS) | VAF 7/47 reads (15%) | called by mutect2, pindel, varscan2
- MICOS10 | c.149dup p.L51Ifs*11 | Frame Shift Ins (INS) | VAF 51/250 reads (20%) | called by mutect2, pindel, varscan2
- OPN1MW | c.898C>A p.H300N | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR8G2P | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 112/629 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- RASA1 | c.655dup p.S219Ffs*4 | Frame Shift Ins (INS) | VAF 27/161 reads (17%) | called by mutect2, pindel, varscan2
- RASA2 | c.1425del p.T476Lfs*2 | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- ROPN1 | c.44del p.P15Rfs*4 | Frame Shift Del (DEL) | VAF 19/130 reads (15%) | called by mutect2, varscan2
- TADA2A | c.754G>T p.E252* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- ABCA13 | c.11811G>T p.L3937= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV101446971; called by muse, mutect2, varscan2
- ACSM5 | c.711C>A p.P237= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV100088967, COSV59374539; called by muse, mutect2, varscan2
- ACTRT2 | c.639G>A p.V213= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV101007471; called by muse, mutect2, varscan2
- ADAMTS14 | c.1167C>A p.G389= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100941602; called by muse, mutect2, varscan2
- ADAMTS16 | c.1215A>T p.A405= | Silent (SNP) | VAF 73/207 reads (35%) | catalogued as COSV99941330; called by muse, mutect2, varscan2
- ADAMTS20 | c.42C>T p.L14= | Silent (SNP) | VAF 21/113 reads (19%) | catalogued as COSV101239366; called by muse, mutect2, varscan2
- ADAMTS5 | c.2151G>A p.Q717= | Silent (SNP) | VAF 79/351 reads (23%) | catalogued as COSV99537650; called by muse, mutect2, varscan2
- ADCY1 | c.3112C>A p.R1038= | Silent (SNP) | VAF 30/137 reads (22%) | catalogued as CM145495, COSV52038469, COSV99812028; called by muse, mutect2, varscan2
- AKAP3 | c.861C>T p.T287= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs1422666501, COSV99962173; called by muse, mutect2, varscan2
- ALB | c.1440C>A p.V480= | Silent (SNP) | VAF 17/104 reads (16%) | catalogued as rs779250426, COSV99891531; called by muse, mutect2, varscan2
- ALKBH3 | c.750G>C p.A250= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV100236329, COSV57023668; called by muse, mutect2, varscan2
- APBB1IP | c.681A>G p.E227= | Silent (SNP) | VAF 37/130 reads (28%) | catalogued as COSV100770897; called by muse, mutect2, varscan2
- ARHGEF11 | c.1005G>A p.A335= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as rs1360345857, COSV100809579; called by muse, mutect2, varscan2
- AZIN1 | c.756C>T p.I252= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as rs1347610790, COSV100457566, COSV61481398; called by muse, mutect2, varscan2
- BCAN | c.246G>T p.L82= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100228131; called by muse, mutect2, varscan2
- BRD8 | c.3318G>A p.L1106= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99648414; called by muse, mutect2, varscan2
- C11orf87 | c.561C>A p.G187= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as rs754666492, COSV100535805; called by muse, mutect2, varscan2
- C2orf42 | c.330G>C p.L110= | Silent (SNP) | VAF 25/122 reads (20%) | catalogued as COSV100033902; called by muse, mutect2, varscan2
- CALCRL | c.813C>T p.A271= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as COSV101130959; called by muse, mutect2, varscan2
- CASS4 | c.1156A>C p.R386= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100824722; called by muse, mutect2, varscan2
- CCDC181 | c.456T>G p.L152= | Silent (SNP) | VAF 33/202 reads (16%) | catalogued as COSV100890327; called by muse, mutect2, varscan2
- CD14 | c.258C>A p.V86= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100117553; called by muse, mutect2, varscan2
- CDH10 | c.1008C>A p.L336= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV100051593, COSV52584313; called by muse, mutect2, varscan2
- CHFR | c.1422C>T p.Y474= (on ENST00000432561 / NM_001161345.1; = p.Y433= on NM_018223.2) | Silent (SNP) | VAF 15/119 reads (13%) | catalogued as rs141349945; called by muse, mutect2, varscan2
- CHST12 | c.129G>A p.P43= | Silent (SNP) | VAF 25/166 reads (15%) | catalogued as rs561223252, COSV51674436; called by muse, mutect2, varscan2
- CNTROB | c.448C>T p.L150= | Silent (SNP) | VAF 21/90 reads (23%) | catalogued as COSV100366501; called by muse, mutect2, varscan2
- CRB1 | c.2823G>T p.P941= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as COSV66335135; called by muse, mutect2, varscan2
- CSMD1 | c.3231T>C p.R1077= (on ENST00000520002; = p.R1076= on NM_033225.6) | Silent (SNP) | VAF 13/118 reads (11%) | catalogued as COSV100148288; called by muse, mutect2, varscan2
- CSMD3 | c.4422T>A p.G1474= (on ENST00000297405 / NM_001363185.1; = p.G1370= on NM_052900.3) | Silent (SNP) | VAF 36/129 reads (28%) | catalogued as COSV99835213, COSV99838796; called by muse, mutect2, varscan2
- CYGB | c.96C>A p.A32= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99506134; called by muse, mutect2, varscan2
- CYLC1 | c.1314G>A p.K438= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV104412416, COSV61415923; called by muse, mutect2
- CYP21A2 | c.1038C>T p.L346= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV64482598; called by muse, mutect2, varscan2
- CYP2F1 | c.135G>A p.L45= | Silent (SNP) | VAF 102/383 reads (27%) | catalogued as rs749306220, COSV100462732; called by muse, mutect2, varscan2
- DCAF12L2 | c.537G>C p.L179= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as COSV100758627; called by muse, mutect2, varscan2
- DCUN1D5 | c.711A>G p.S237= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV99499102; called by muse, mutect2, varscan2
- DDX59 | c.1659A>T p.S553= | Silent (SNP) | VAF 32/167 reads (19%) | catalogued as COSV100494556, COSV58752738; called by muse, mutect2, varscan2
- DICER1 | c.2577G>T p.R859= | Silent (SNP) | VAF 8/109 reads (7%) | catalogued as rs1010614154, COSV100602129; ClinVar: likely benign; called by muse, mutect2
- DISP2 | c.3048T>A p.T1016= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as COSV99140031; called by muse, mutect2, varscan2
- DNAJC3 | c.1254A>T p.A418= | Silent (SNP) | VAF 35/161 reads (22%) | catalogued as COSV100953375; called by muse, mutect2, varscan2
- DPP6 | c.1068A>T p.L356= (on ENST00000377770 / NM_001364500.2; = p.L294= on NM_001936.5) | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as COSV100125793; called by muse, mutect2, varscan2
- ENAM | c.3384C>T p.T1128= | Silent (SNP) | VAF 23/85 reads (27%) | catalogued as COSV101253117; called by muse, mutect2, varscan2
- EYA4 | c.528C>A p.A176= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as COSV100765904, COSV62050945; called by muse, mutect2, varscan2
- FAM228A | c.55A>C p.R19= | Silent (SNP) | VAF 16/82 reads (20%) | catalogued as COSV99722546; called by muse, mutect2, varscan2
- FCSK | c.213G>A p.L71= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99850906; called by muse, mutect2
- FMNL2 | c.261G>T p.L87= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV99979751; called by muse, mutect2
- FOXB2 | c.750C>A p.G250= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100942344; called by muse, mutect2, varscan2
- GDPD5 | c.1755C>A p.T585= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV100409311, COSV61129751; called by muse, mutect2, varscan2
- GRID1 | c.1254G>A p.E418= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100024252; called by muse, mutect2, varscan2
- HDAC9 | c.2487G>A p.Q829= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV101286778; called by muse, mutect2, varscan2
- HSPG2 | c.3267C>T p.I1089= | Silent (SNP) | VAF 25/116 reads (22%) | catalogued as COSV101020578; called by muse, mutect2, varscan2
- ICE1 | c.4917G>A p.L1639= | Silent (SNP) | VAF 16/263 reads (6%) | catalogued as COSV99664834; called by muse, mutect2
- IGSF1 | c.2397C>T p.C799= | Silent (SNP) | VAF 55/201 reads (27%) | catalogued as COSV100812099; called by muse, mutect2, varscan2
- IL36A | c.342G>A p.R114= | Silent (SNP) | VAF 12/143 reads (8%) | catalogued as rs1031389187, COSV99382122; called by muse, mutect2
- ILDR2 | c.1161G>T p.G387= | Silent (SNP) | VAF 66/388 reads (17%) | catalogued as rs757541566, COSV99613916; called by muse, mutect2, varscan2
- INTS8 | c.450A>T p.A150= | Silent (SNP) | VAF 12/189 reads (6%) | catalogued as COSV100569284; called by muse, mutect2
- IPO5 | c.2289A>T p.S763= | Silent (SNP) | VAF 34/182 reads (19%) | catalogued as COSV99847327; called by muse, mutect2, varscan2
- ITGAM | c.2727C>G p.P909= (on ENST00000648685 / NM_001145808.2; = p.P908= on NM_000632.4) | Silent (SNP) | VAF 10/170 reads (6%) | catalogued as COSV99792473; called by muse, mutect2
- KCNIP3 | c.465C>T p.L155= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as COSV54673101; called by muse, mutect2, varscan2
- KLHL1 | c.1443G>T p.L481= | Silent (SNP) | VAF 12/238 reads (5%) | catalogued as COSV100917332; called by muse, mutect2
- LATS2 | c.2079G>T p.L693= | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as COSV101231575; called by muse, mutect2, varscan2
- LAYN | c.453G>T p.V151= (on ENST00000375615 / NM_001258390.1; = p.V143= on NM_178834.5) | Silent (SNP) | VAF 25/126 reads (20%) | catalogued as COSV65104619; called by muse, mutect2, varscan2
- LRFN4 | c.1398C>A p.P466= | Silent (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2
- LYPD3 | c.720G>T p.R240= | Silent (SNP) | VAF 41/141 reads (29%) | catalogued as COSV99747045; called by muse, mutect2, varscan2
- LYST | c.111G>T p.T37= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as COSV101089462; called by muse, mutect2, varscan2
- MCF2L2 | c.414T>A p.S138= | Silent (SNP) | VAF 16/79 reads (20%) | catalogued as COSV100192650; called by muse, mutect2, varscan2
- MDM4 | c.705A>T p.T235= | Silent (SNP) | VAF 19/107 reads (18%) | catalogued as COSV100914458; called by muse, mutect2, varscan2
- MLKL | c.834A>G p.Q278= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs770026452, COSV100087344; called by muse, mutect2, varscan2
- MMS22L | c.552A>G p.L184= | Silent (SNP) | VAF 33/118 reads (28%) | catalogued as rs1374946007, COSV99246872; called by muse, mutect2, varscan2
- MOGS | c.1293C>T p.P431= | Silent (SNP) | VAF 8/132 reads (6%) | catalogued as rs905902828; called by muse, mutect2
- MRTFB | c.2526G>T p.P842= (on ENST00000571589 / NM_001365412.2; = p.P792= on NM_014048.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/167 reads (13%) | catalogued as COSV100371319, COSV57957537; called by muse, mutect2, varscan2
- MS4A14 | c.150C>T p.I50= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV100279554; called by muse, mutect2, varscan2
- MUC5AC | c.609C>T p.Y203= | Silent (SNP) | VAF 30/108 reads (28%) | catalogued as rs371327298; called by muse, varscan2
- MUC5B | c.14724G>C p.V4908= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101500372; called by muse, mutect2, varscan2
- MYO7B | c.1156C>T p.L386= | Silent (SNP) | VAF 18/157 reads (11%) | catalogued as COSV101268197, COSV67347561; called by muse, mutect2, varscan2
- MYT1L | c.733C>A p.R245= | Silent (SNP) | VAF 25/171 reads (15%) | catalogued as COSV67722156; called by muse, mutect2, varscan2
- NAA30 | c.474G>T p.A158= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV100035898; called by muse, mutect2, varscan2
- NAV2 | c.1209G>T p.G403= (on ENST00000396087 / NM_001244963.2; = p.G380= on NM_145117.5) | Silent (SNP) | VAF 64/254 reads (25%) | catalogued as COSV100586259; called by muse, mutect2, varscan2
- NCKAP1L | c.1893C>T p.H631= | Silent (SNP) | VAF 67/274 reads (24%) | catalogued as COSV99515123; called by muse, mutect2, varscan2
- NLRP11 | c.2067G>T p.R689= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV100789744; called by muse, mutect2, varscan2
- NLRP3 | c.672G>T p.G224= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs200354644, COSV100276101, COSV100276665; called by muse, mutect2, varscan2
- NOD2 | c.2700C>A p.S900= | Silent (SNP) | VAF 19/137 reads (14%) | catalogued as COSV100318573, COSV56053763; called by muse, mutect2, varscan2
- NPAS3 | c.2145C>A p.V715= (on ENST00000356141 / NM_001164749.2; = p.V683= on NM_022123.3) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV100640241; called by muse, mutect2
- NT5C1B | c.771C>A p.T257= (on ENST00000359846 / NM_001199086.2; = p.T197= on NM_033253.4) | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV100410061; called by muse, mutect2, varscan2
- OR10C1 | c.126C>A p.G42= (on ENST00000622521; = p.G40= on NM_013941.3) | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as rs1197544121, COSV101010838; called by muse, mutect2, varscan2
- OR10S1 | c.834C>A p.S278= | Silent (SNP) | VAF 27/224 reads (12%) | catalogued as COSV101602497, COSV73342693; called by muse, mutect2, varscan2
- OR2T2 | c.42C>A p.V14= | Silent (SNP) | VAF 24/271 reads (9%) | catalogued as COSV61619363; called by muse, mutect2
- OR2T3 | c.807C>T p.S269= | Silent (SNP) | VAF 40/528 reads (8%) | catalogued as COSV100613243; called by muse, mutect2
- OR2T34 | c.807C>T p.S269= | Silent (SNP) | VAF 18/75 reads (24%) | catalogued as COSV100170375; called by muse, mutect2, varscan2
- OR4C16 | c.348G>T p.T116= | Silent (SNP) | VAF 69/338 reads (20%) | catalogued as rs545444808, COSV100114074; called by muse, mutect2, varscan2
- OR52M1 | c.441G>A p.G147= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV100798589; called by muse, mutect2, varscan2
- OR5M10 | c.432G>T p.L144= | Silent (SNP) | VAF 39/179 reads (22%) | catalogued as COSV73242365; called by muse, mutect2, varscan2
- OR6T1 | c.120A>T p.T40= | Silent (SNP) | VAF 47/213 reads (22%) | catalogued as COSV100189976; called by muse, mutect2, varscan2
- OR8H1 | c.909C>A p.V303= | Silent (SNP) | VAF 46/250 reads (18%) | catalogued as rs1405126089, COSV100477110, COSV57294061; called by muse, mutect2, varscan2
- OTUD6A | c.552G>A p.E184= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as COSV100611000; called by muse, mutect2, varscan2
- P2RY8 | c.264C>T p.H88= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV101184035; called by muse, mutect2, varscan2
- PADI3 | c.69G>A p.V23= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV100968494; called by muse, mutect2
- PCDH11X | c.3870C>T p.C1290= | Silent (SNP) | VAF 98/429 reads (23%) | catalogued as rs146706969, COSV53488176; called by muse, mutect2, varscan2
- PDE6B | c.345G>A p.P115= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs780426891, COSV55328931; called by muse, varscan2
- PHC1 | c.2310G>A p.P770= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs749091507, COSV101418612; called by muse, mutect2
- PIWIL1 | c.2088G>C p.R696= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV99806439; called by muse, mutect2, varscan2
- PLEC | c.5895G>T p.R1965= (on ENST00000322810 / NM_201380.4; = p.R1855= on NM_000445.5) | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100514467; called by muse, mutect2, varscan2
- PRAME | c.1128C>T p.A376= | Silent (SNP) | VAF 27/159 reads (17%) | catalogued as COSV101287090; called by muse, mutect2, varscan2
- RASL11B | c.378T>C p.Y126= | Silent (SNP) | VAF 19/144 reads (13%) | catalogued as rs771325908, COSV99954459; called by muse, mutect2, varscan2
- RFX1 | c.1272C>T p.A424= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as COSV99586112; called by muse, mutect2, varscan2
- RGS8 | c.303G>T p.L101= (on ENST00000367556 / NM_001369564.2; = p.L119= on NM_033345.3) | Silent (SNP) | VAF 68/366 reads (19%) | catalogued as COSV99276685; called by muse, mutect2, varscan2
- RHBG | c.1215T>C p.S405= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as COSV99659614; called by muse, mutect2, varscan2
- RPE65 | c.333C>A p.P111= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV99253713; called by muse, varscan2
- RTL4 | c.903G>A p.P301= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as rs752942950, COSV61206601, COSV61207117; called by muse, mutect2, varscan2
- RXFP2 | c.2058G>A p.L686= | Silent (SNP) | VAF 26/103 reads (25%) | catalogued as COSV100034347; called by muse, mutect2, varscan2
- SACS | c.1962G>T p.V654= | Silent (SNP) | VAF 30/128 reads (23%) | catalogued as COSV101207463, COSV66547794; called by muse, mutect2, varscan2
- SATB1 | c.1635G>T p.L545= | Silent (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100113203; called by muse, mutect2, varscan2
- SCARF2 | c.888G>A p.T296= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs551075345, COSV99839305; called by muse, mutect2, varscan2
- SCML2 | c.522G>T p.V174= | Silent (SNP) | VAF 27/226 reads (12%) | catalogued as COSV99319018; called by muse, mutect2, varscan2
- SERPINI1 | c.969A>T p.T323= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as COSV99855088; called by muse, mutect2, varscan2
- SHPRH | c.1056A>G p.T352= | Silent (SNP) | VAF 27/125 reads (22%) | catalogued as COSV99262127; called by muse, mutect2, varscan2
- SIGLEC1 | c.258C>G p.R86= | Silent (SNP) | VAF 4/74 reads (5%) | catalogued as COSV99165760; called by muse, mutect2
- SUGCT | c.540G>T p.S180= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV59327877, COSV59339955; called by muse, mutect2, varscan2
- TACC2 | c.954G>A p.G318= | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV57763257; called by muse, mutect2, varscan2
- TCOF1 | c.3514C>T p.L1172= (on ENST00000377797 / NM_001135243.1; = p.L1095= on NM_000356.4) | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV100077489; called by muse, mutect2
- TFDP2 | c.660G>T p.L220= (on ENST00000489671 / NM_001178139.2; = p.L160= on NM_006286.5) | Silent (SNP) | VAF 18/149 reads (12%) | catalogued as COSV100050917; called by muse, mutect2, varscan2
- THEG | c.1107A>G p.P369= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV100700618; called by muse, mutect2, varscan2
- TIAM1 | c.1947G>T p.V649= | Silent (SNP) | VAF 44/186 reads (24%) | catalogued as COSV99735360; called by muse, varscan2
- TIAM1 | c.651G>T p.R217= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV99735363; called by muse, mutect2, varscan2
- TMEM127 | c.462C>T p.I154= | Silent (SNP) | VAF 25/145 reads (17%) | catalogued as COSV51498667, COSV99302624; called by muse, mutect2, varscan2
- TMEM177 | c.537G>A p.G179= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV99733620; called by muse, mutect2, varscan2
- TPO | c.2787G>T p.L929= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100221130; called by muse, mutect2
- TRAF2 | c.108C>A p.A36= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV99916519; called by muse, mutect2, varscan2
- TRIM48 | c.651G>C p.L217= | Silent (SNP) | VAF 8/96 reads (8%) | catalogued as COSV101338279, COSV70161848; called by muse, mutect2
- UPF2 | c.717A>T p.S239= | Silent (SNP) | VAF 20/115 reads (17%) | catalogued as COSV100707275; called by muse, mutect2, varscan2
- USP24 | c.1674G>A p.L558= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV99599800; called by muse, mutect2, varscan2
- USP26 | c.927G>A p.V309= | Silent (SNP) | VAF 22/113 reads (19%) | catalogued as rs771159887, COSV100896644; called by muse, mutect2, varscan2
- WDR49 | c.696G>T p.G232= (on ENST00000308378 / NM_001366158.1; = p.G573= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 41/218 reads (19%) | catalogued as rs771444929, COSV100392853; called by muse, mutect2, varscan2
- WNK2 | c.5130C>T p.V1710= (on ENST00000297954 / NM_001282394.1; = p.V1673= on NM_006648.3) | Silent (SNP) | VAF 14/154 reads (9%) | catalogued as COSV99942560; called by muse, mutect2
- XIRP2 | c.8613C>A p.P2871= (on ENST00000628543; = p.P3046= on NM_152381.6) | Silent (SNP) | VAF 25/211 reads (12%) | catalogued as COSV54684183; called by muse, mutect2, varscan2
- XYLT2 | c.2073C>T p.I691= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs751189558, COSV99190938; called by muse, mutect2, varscan2
- ZFHX4 | c.8478C>A p.T2826= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV51482830; called by muse, mutect2, varscan2
- ZNF124 | c.615C>A p.P205= (on ENST00000543802 / NM_001297568.1; = p.P143= on NM_003431.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 42/189 reads (22%) | catalogued as COSV100517796; called by muse, mutect2, varscan2
- ZNF831 | c.3297C>A p.P1099= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV100926044; called by muse, mutect2, varscan2
- C4orf50 | c.-4947C>A | 5'UTR (SNP) | VAF 9/61 reads (15%) | catalogued as COSV99289660; called by muse, mutect2, varscan2
- C7orf66 | n.143del | RNA (DEL) | VAF 11/70 reads (16%) | called by pindel, varscan2
- CCNQP1 | n.160C>T | RNA (SNP) | VAF 48/204 reads (24%) | called by muse, mutect2, varscan2
- CDH11 | c.1895-650G>A | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as COSV99218505; called by muse, mutect2
- COL27A1 | c.2269-214G>A | Intron (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100621022; called by muse, mutect2, varscan2
- DSCR4 | n.403C>A | RNA (SNP) | VAF 40/165 reads (24%) | catalogued as COSV100077312; called by muse, mutect2, varscan2
- DST | c.4297-4023G>A | Intron (SNP) | VAF 40/257 reads (16%) | catalogued as COSV55042876; called by muse, mutect2, varscan2
- FOLH1B | n.898C>A | RNA (SNP) | VAF 19/114 reads (17%) | called by muse, mutect2, varscan2
- KNOP1P1 | n.198G>A | RNA (SNP) | VAF 28/110 reads (25%) | called by muse, varscan2
- KNOP1P1 | n.254C>T | RNA (SNP) | VAF 15/62 reads (24%) | called by muse, varscan2
- SREBF1 | c.92-3002T>A | Intron (SNP) | VAF 7/57 reads (12%) | catalogued as COSV99888911; called by muse, varscan2
- SSPOP | n.4408C>T | RNA (SNP) | VAF 7/33 reads (21%) | catalogued as rs767323825, COSV100022210, COSV100022541; called by muse, mutect2, varscan2
- SSPOP | n.15146A>T | RNA (SNP) | VAF 6/28 reads (21%) | catalogued as COSV100947451; called by muse, mutect2
- VPS11 | c.-916T>A | 5'UTR (SNP) | VAF 14/80 reads (18%) | catalogued as COSV100333785; called by muse, mutect2, varscan2
- XIRP2 | c.*534C>T | 3'UTR (SNP) | VAF 18/216 reads (8%) | catalogued as COSV99743203; called by muse, mutect2
- ZNF658B | n.1159A>T | RNA (SNP) | VAF 68/728 reads (9%) | called by muse, mutect2
